Somatic mutation profile of tumor specimen TCGA-BA-5153-01A (aliquot TCGA-BA-5153-01A-01D-1434-08) from TCGA case TCGA-BA-5153, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G2; Age at diagnosis: 51.3 years (18,743 days).
Specimen TCGA-BA-5153-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 661d8cb4-56ca-47b3-9ee7-4b311d9e30a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-5153-10A (Blood Derived Normal), aliquot TCGA-BA-5153-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f31de1d9-2f58-4fdb-82a4-433120e15e6f

The open-access MAF lists 41 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 32, Silent 7, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASAP1 | c.1646A>C p.D549A | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV100728073; called by muse, mutect2, varscan2
- ASPSCR1 | c.727G>C p.V243L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV100145094; called by muse, mutect2, varscan2
- C2orf68 | c.367A>T p.I123F | Missense Mutation (SNP) | VAF 187/521 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100108365; called by muse, mutect2, varscan2
- CCDC181 | c.201T>A p.D67E | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100890418; called by muse, mutect2, varscan2
- CCN3 | c.7_8del p.S3Cfs*87 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs1222215691; called by pindel, varscan2
- CDH3 | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1284406451, COSV99869502; called by muse, mutect2, varscan2
- CENPS-CORT | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100471917; called by muse, mutect2
- CHPF2 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1489909980, COSV99223214; called by muse, mutect2, varscan2
- CYLD | c.2038A>T p.K680* | Nonsense Mutation (SNP) | VAF 38/67 reads (57%) | catalogued as COSV100282820; called by muse, mutect2, varscan2
- DENND1C | c.401T>C p.F134S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV101200274; called by muse, mutect2, varscan2
- DRD2 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); catalogued as rs766300123, COSV100670291; called by muse, mutect2, varscan2
- EIF4G3 | c.2015C>G p.P672R | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99946082; called by muse, mutect2, varscan2
- ERN2 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV99891683; called by muse, mutect2, varscan2
- GNA15 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1417467645, COSV99505511; called by muse, mutect2, varscan2
- GRIK4 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 150/401 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.82); catalogued as COSV70808729; called by muse, mutect2, varscan2
- HAL | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV99701730; called by muse, mutect2, varscan2
- IGKV1-27 | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 84/342 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs763040811; called by muse, mutect2, varscan2
- KCNK5 | c.642C>A p.N214K | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV100851974; called by muse, mutect2, varscan2
- KRT2 | c.1567G>T p.G523C | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as rs567369735, COSV59011224; called by muse, mutect2, varscan2
- MYH9 | c.4454T>C p.L1485P | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99340104; called by muse, mutect2, varscan2
- MYLK | c.3704C>T p.A1235V | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV100659863; called by muse, mutect2, varscan2
- OPCML | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs781145977, COSV100106246; called by muse, mutect2, varscan2
- OR2W1 | c.517A>G p.I173V | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101013958; called by muse, mutect2, varscan2
- PHF5A | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs1331579175, COSV99346867; called by muse, mutect2, varscan2
- PPFIBP2 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs538034375, COSV100207186; called by muse, mutect2, varscan2
- RECK | c.1829G>A p.C610Y | Missense Mutation (SNP) | VAF 121/322 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100937706; called by muse, mutect2, varscan2
- SEMA4F | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs774966104, COSV60282963, COSV60285954; called by muse, mutect2, varscan2
- SHBG | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs754172970, COSV52646702; called by muse, mutect2, varscan2
- SIAH3 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs762491862, COSV68551972; called by muse, mutect2, varscan2
- SLC26A2 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99640458; called by muse, mutect2, varscan2
- SMC4 | c.3472G>A p.D1158N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100557612; called by muse, mutect2
- TMEM132A | c.619T>A p.Y207N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV99137848; called by muse, mutect2, varscan2
- TTN | c.29189T>C p.I9730T (on ENST00000591111; = p.I8803T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/276 reads (33%) | PolyPhen probably damaging (0.996); catalogued as rs1468010768, COSV100636155; called by muse, mutect2, varscan2
- ZNF516 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374836539; called by muse, mutect2, varscan2
- HIVEP3 | c.4134C>T p.P1378= | Silent (SNP) | VAF 108/254 reads (43%) | catalogued as rs1261709494, COSV56018242; called by muse, mutect2, varscan2
- LDLRAD4 | c.723C>G p.T241= | Silent (SNP) | VAF 71/172 reads (41%) | catalogued as COSV100761961, COSV100762893; called by muse, mutect2, varscan2
- PCDHB3 | c.69G>A p.G23= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs1164608040, COSV99167229; called by muse, mutect2, varscan2
- RP1 | c.540C>T p.F180= | Silent (SNP) | VAF 107/281 reads (38%) | catalogued as COSV99609322; called by muse, mutect2, varscan2
- SYNE2 | c.6300C>T p.I2100= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs755549215, COSV100648658; called by muse, mutect2, varscan2
- TEX35 | c.690T>A p.T230= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99275139; called by muse, mutect2, varscan2
- ZNF429 | c.303G>A p.R101= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100642072; called by muse, mutect2, varscan2
